Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4166, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4166-01A (Primary Tumor).

[page 1 of 2]
.....

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

- 1: SP: Lt. kidney and portion of adrenal gland [REDACTED]
2: SP: Remainder of adrenal gland [REDACTED]
3: SP: Para-aortic lymph nodes [REDACTED]

DIAGNOSIS:

- 1) KIDNEY AND PORTION OF ADRENAL GLAND, LEFT; RESECTION:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV.
- THE TUMOR IS PRESENT AT TWO SEPARATE FOCI, 5.0 CM AND 0.8 CM IN SIZE RESPECTIVELY.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF LARGE RENAL VEIN IS IDENTIFIED. TUMOR EMBOLI IN SMALL-SIZE LYMPHOVASCULAR CHANNELS ARE NOTED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL BENIGN SIMPLE CORTICAL CYSTS, OTHERWISE UNREMARKABLE.
- BENIGN ADRENAL GLAND.
- 2) ADRENAL GLAND, REMAINDER; RESECTION:
- HISTOLOGICALLY BENIGN ADRENAL GLAND TISSUE.
- 3) LYMPH NODES, PARA-AORTIC; EXCISION:
- TEN BENIGN LYMPH NODES.
- [REDACTED]
- [REDACTED]

1) The specimen is received fresh for frozen section, labeled, "Lt. kidney and portion of adrenal gland ". It consists of a kidney with perirenal fat measuring 19 x 9.0 x 8.0 cm. The kidney measures 14.0 x 6.5 x 4.2 cm and on sectioning, the specimen reveals a multinodular tan-yellow tumor which is bulging outside into the perirenal fat and measuring 5.0 x 3.5 x 2.5 cm. The tumor is localized on the lateral lower pole of the kidney. A separate nodule is identified and measures 0.8 x 0.7 x 0.7 cm. This nodule is 2.0 cm away from the main tumor. The medulla also contains a cyst with a smooth anterior surface which measures 2.0 x 1.6 x 1.2 cm. The renal cortex measures 1.0 cm in thickness and is otherwise unremarkable. The adrenal is identified and measures 3.5 x 1.2 x 0.7 cm and on sectioning is unremarkable. Representative sections of the specimen are submitted:

Summary of Sections:

FSC - frozen section control

[page 2 of 2]
VM – vascular margin
UM – ureter margin
T - tumor
ST – separate nodule of tumor
C – cyst
RP – unremarkable renal parenchyma
A – adrenal
PF – perirenal fat

2) The specimen is received in formalin, labeled "Remainder of adrenal gland". It consists of multiple fragments of adipose tissue and adrenal gland measuring in aggregate, 4.5 x 3.5 x 3.0 cm. Representative sections of the specimen are submitted.

Summary of Sections:
AG – adrenal gland

3) The specimen is received in formalin, labeled "Para-aortic lymph nodes". It consists of multiple pieces of adipose tissue measuring in aggregate, 1.7 x 1.5 x 1.0 cm, which reveal a lymph node measuring 1.2 x 0.7 x 0.5 cm. Entirely submitted.

Summary of Sections:
LN - lymph node

Summary of Sections:

Part 1: SP: Lt. kidney and portion of adrenal gland

Block	Sect. Site	PCs
1	a	1
3	c	3
1	fsc	1
2	pf	2
1	rp	1
1	st	1
6	t	6
1	um	1
1	vm	1

Part 2: SP: Remainder of adrenal gland

Block	Sect. Site	PCs
3	ag	3

Part 3: SP: Para-aortic lymph nodes

Block	Sect. Site	PCs
2	ln	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA. FAVOR CLEAR CELL TYPE
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 9bc55c8e-e65c-419c-97d1-d2a83c941e01 (TCGA-BP-4166.E1EFB0CA-FF0C-454A-8A82-AB49F7816624.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).